Gene-level copy-number profile of tumor specimen TCGA-CV-6959-01A from TCGA case TCGA-CV-6959, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 48.4 years (17,679 days).
Specimen TCGA-CV-6959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.878249b0-64a0-4ed4-90cf-746cbe4a475c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6959-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3c247ce-7ecb-4b85-b6bd-edc409c22237

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,079; copy number 2: 5,824; copy number 3: 28,786; copy number 4: 9,546; copy number 5: 12,873; copy number 6: 560; copy number 7: 710; copy number 9: 130; copy number 12: 137; copy number 14: 73; copy number 24: 28; copy number 28: 60; copy number 31: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6959-01A-11D-1910-01): tumor purity 0.4, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,152 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr7:54,933,699–57,777,521, 136 genes, copy number 12–31 (broad region; genes not listed).
- chr11:55,262,155–57,237,235, 130 genes, copy number 9 (broad region; genes not listed).
- chr20:30,278,906–31,801,805, 43 genes, copy number 12–24 (within-gene range 5–24): LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2.
- chr20:31,944,337–35,607,562, 133 genes, copy number 14–28 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
